FM case AD5640 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Nevi and Melanomas.
https://portal.gdc.cancer.gov/cases/7a6b61e9-2869-4ef5-9ba7-54447e6eaab9

Female, 79.9 years: Melanoma, NOS (ICD-O-3 8720/3); specimen biopsied or resected from the vulva. Tumor nuclei on the sequenced sample's slide: 40% (pathologist estimate recorded by GDC). Sample type: Tumor.
